TCGA case TCGA-MA-AA3Z — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bc2003b9-d489-4559-8672-d9fd2d82f2e8

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: United States; Age at index: 43 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 43.2 years (15,762 days); Year of diagnosis: 2013; Method of diagnosis: Biopsy; AJCC pathologic T: T1b2; AJCC pathologic N: N0; AJCC pathologic M: M0; FIGO stage: Stage IB2; FIGO staging edition year: 2009; Tumor grade: GX; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Brachytherapy, High Dose; Treatment intent type: Adjuvant; Treatment dose: 2,800 cGy; Treatment outcome: Complete Response; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Number of cycles: 6; Treatment outcome: Complete Response; Chemo concurrent to radiation: Yes; Prescribed dose: 70; Timepoint category: Postoperative; Treatment frequency: Once Weekly.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, 3D Conformal; Treatment intent type: Adjuvant; Treatment dose: 5,040 cGy; Treatment outcome: Complete Response; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative; Treatment anatomic sites: Pelvis.

Follow-up (15 entries)
- Day 36 (prior to adjuvant therapy): ECOG performance status: 1.
- Day 41 (preoperative): Days to imaging: 41 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Paraaortic Lymph Node Involvement.
- Day 41 (preoperative): Days to imaging: 41 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Bladder Involvement.
- Day 41 (preoperative): Days to imaging: 41 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Pelvic Lymph Node Involvement.
- Day 41 (preoperative): Days to imaging: 41 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Supraclavicular Lymph Node Involvement.
- Day 41 (preoperative): Days to imaging: 41 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Extra-Pelvic Metastatic Disease.
- Day 41 (preoperative): Days to imaging: 41 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Parametrium Involvement.
- Day 52 (preoperative): Days to imaging: 52 days; Imaging type: PET; Imaging result: Negative; Imaging anatomic site: Cervix Uteri; Imaging findings: Bladder Involvement; Imaging suv: 28.8.
- Day 52 (preoperative): Days to imaging: 52 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Parametrium Involvement.
- Day 52 (preoperative): Days to imaging: 52 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Pelvic Lymph Node Involvement.
- Day 52 (preoperative): Days to imaging: 52 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Extra-Pelvic Metastatic Disease.
- Day 52 (preoperative): Days to imaging: 52 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Paraaortic Lymph Node Involvement.
- Day 52 (preoperative): Days to imaging: 52 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Supraclavicular Lymph Node Involvement.
- Days to follow up: 469 days (1.3 years); Disease response: Tumor Free.
- Day 595 (post adjuvant therapy): Disease response: Tumor Free; ECOG performance status: 0.

Molecular and laboratory tests
- Human Papillomavirus: Positive.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Former User.
- Timepoint category: Prior to Diagnosis; Comorbidities: Human Papillomavirus Infection; Risk factors: Human Papillomavirus Infection.
- Timepoint category: Initial Diagnosis; Weight: 84 kg; Height: 160 cm; BMI: 32.8.
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal; Pregnant at diagnosis: No.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 4+; Pregnancy outcome: Live Birth.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-MA-AA3Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 230 mg.
  Slide TCGA-MA-AA3Z-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-MA-AA3Z-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-MA-AA3Z-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Tumor status: Tumor free; Live birth pregnancy count: 5; Total pregnancy count: 5; Tobacco smoking history indicator: 1; Performance status timing: Pre-Adjuvant Therapy; Treatment outcome first course: Complete Remission/Response; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Keratinization squamous cell: Non-keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Lymph nodes examined: No; HPV types other: There are several types of HPV the patient could be positive for; HPV typing method other: HPV Hybrid Capture II; New tumor event diagnosis indicator: No.
- Fdg or ct pet performed outcomes: Fedpet or ct results: Bladder Absent; Fedpet or ct results: Extra-Pelvic Metastatic Disease Absent; Fedpet or ct results: Parametrium Absent; Fedpet or ct results: Paraaortic Nodes Absent; Fedpet or ct results: Pelvic Nodes Absent; Fedpet or ct results: Supraclavicular Absent.
- Diagnostic ct result outcomes: Ct scan preop results: Bladder Absent; Ct scan preop results: Extra-Pelvic Metastatic Disease Absent; Ct scan preop results: Parametrium Absent; Ct scan preop results: Paraaortic Nodes Absent; Ct scan preop results: Pelvic Nodes Absent; Ct scan preop results: Supraclavicular Absent.
- Human papillomavirus types: HPV types positive: Other HPV type(s).
- Treatment, Radiation therapy info: Brachytherapy type: HDR; Radiation therapy xrt type: 3D conformal.
- Treatment, Concurrent prescription treatment info, Concurrent prescription treatment: Chemo concurrent fractions total: 6.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Performance status timing: Post-Adjuvant Therapy; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 595 days; disease-specific survival: no event (censored), 595 days; disease-free interval: no event (censored), 595 days; progression-free interval: no event (censored), 595 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-MA-AA3Z-01A-11D-A386-01): tumor purity 0.76, ploidy 2, whole-genome doublings 0.
